CCDI case PBCIKN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5e1c9397-8164-4dff-8203-51449dd8ed5f

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.1 years (4,059 days).

Biospecimens (3 samples)
- Sample 0DSP23: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSP28: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSP2K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
